CCG case CUPP-B38Q — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0e9c4c16-b5cd-4760-8138-fd4e52a70b6c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Year of birth: 1939; Vital status: Dead; Days to death: 114 days; Year of death: 2018; Cause of death: Cancer Related.

Diagnoses (1)
1. Desmoplastic small round cell tumor: ICD-O-3 morphology code: 8806/6; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Bone, NOS; Classification of tumor: metastasis; Age at diagnosis: 78.7 years (28,740 days); Year of diagnosis: 2018; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC clinical T: TX; AJCC clinical M: M1; AJCC clinical stage: Stage III; AJCC pathologic T: TX; AJCC pathologic M: M1; AJCC pathologic stage: Stage III; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Bone, NOS / Liver / Lung, NOS / Peritoneum, NOS / Adrenal gland, NOS.
   Pathology details: Consistent pathology review: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Timepoint category: Postoperative.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Timepoint category: First Treatment.

Follow-up (2 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 40; ECOG performance status: 3.
- Days to follow up: 114 days; Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 88 kg; Height: 170 cm; BMI: 30.4.
- Timepoint category: Prior to Diagnosis; Comorbidities: Coronary Artery Disease / Diabetes, NOS / Hypertension.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B38Q-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Lymphocytes; Preservation method: Frozen.
- Sample CUPP-B38Q-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B38Q-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 50; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 60; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
